Gene-level copy-number profile of tumor specimen TCGA-06-1087-01A from TCGA case TCGA-06-1087, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.7 years (27,658 days).
Specimen TCGA-06-1087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c4d21b39-7d27-4f00-8ed7-367f7da0bb38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-1087-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5065f49-5a43-4d2c-8d8d-aa92671c2dc5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 58; copy number 2: 9,984; copy number 3: 16,419; copy number 4: 29,412; copy number 5: 2,925; copy number 6: 949; copy number 15: 1; copy number 26: 12; copy number 27: 5; copy number 32: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-1087-01A-02D-0517-01): tumor purity 0.74, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:48,446,036–48,993,046, 12 genes (within-gene range 0–2): ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2.
- chr10:87,659,613–87,747,705, 1 gene (within-gene range 0–2): PAPSS2.
- chr10:87,859,158–88,259,372, 7 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr10:88,585,638–88,752,756, 7 genes: Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38.
- chr10:89,205,629–89,414,557, 4 genes (within-gene range 0–2): CH25H, LIPA, IFIT2, AL353751.1.
- chr10:89,378,056–89,840,861, 16 genes: IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, MTND5P42, LINC00865, MARK2P16.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:13,710,531–14,400,963, 1 gene, copy number 32 (within-gene range 3–32): LINC00276.
- chr2:14,274,622–14,274,725, 1 gene, copy number 32: RNU6-1288P.
- chr2:15,903,669–16,204,226, 11 genes, copy number 26: AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1.
- chr2:16,227,027–16,228,194, 1 gene, copy number 26: AC010745.3.
- chr2:20,386,386–20,480,955, 5 genes, copy number 27 (within-gene range 3–27): SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA.
- chr2:22,861,552–22,861,884, 1 gene, copy number 15: RN7SKP27.
- chr2:52,864,235–52,883,455, 2 genes, copy number 32 (within-gene range 3–32): AC010967.2, AC010967.3.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
